Surgical pathology report (de-identified scan), TCGA case TCGA-CD-A4MG, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-A4MG-01A (Primary Tumor).

[page 1 of 5]
Fax:

Clinical Case Report

(For Collection of Cancerous Tissue)

1CD-0-3

adenocarcinoma, diffuse type 814513

Site: Stomach, cardia, NOS C16.0

ju
10/3/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status		Race
	1m 64	☐ Single ☒ Married		VIETNAMESE
Gender	Weight	☐ Divorced ☐ Widow		Blood Pressure
☒ Male ☐ Female	57 kg			121/8
				Heart Rate

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain; tired of eating
Symptoms: Black & tarry stool; weight loss.
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses		# of Pregnancies
	Date of Last Menses		# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		Hormone Replacement Therapy: _____

SOCIAL HISTORY					
Occupation:			Environmental Hazards:		
Smoking History					
Current Status	TYPE	Packs/day	Duration	When Quit	
☒ YES ☐ NO		1 p/day	30 (yrs)	1 year ago (yr)	
Alcohol Consumption					
Current Status	TYPE	Drinks/day	Duration	When Quit	
☒ YES ☐ NO		2 drinks/day	30 (yrs)	1 year ago (yr)	
Drug Use					
Current Status	TYPE	Frequency	Duration	When Quit	
☐ YES ☒ NO			(yrs)	(yr)	

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA							
Test	Result	Date	Test	Result	Date		
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____			
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____			
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____			
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____			
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____			
B/T Cell Markers:							

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	an ulceration was seen at the pylorus.	
MRI		
Biopsy		
	Adenocarcinoma	

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T 3 N 0 M 0 Stage: II	

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Extended gastrectomy		
Primary Tumor		
Organ	Detailed Location	Size
Stomach Tumor	Cardia	3 x 3 x 1 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 3 N 0 M 0 Stage: II		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____

____ Date:

Time: _____

Preserved by: _____

____ Date:

Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	3 x 3 x 1 cm	cardia	cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃ N ₀ M ₀ Stage: II			
Notes:			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION				STRUCTURAL PATTERN			
	+	-			+	-	
Diffuse	X		Streaming				
Mosaic	X		Storiform				
Necrosis	X		Fibrosis				
Lymphocytic Infiltration	X		Palisading				
Vascular Invasion	X		Cystic Degeneration				
Clusterized	X		Bleeding				
Alveolar Formation	X		Myxoid Change				
Indian File			Psamomma/Calcification				

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Otherwise Specified:

D1 50% D2 35% D3 50% D4 35% Adenocarcinoma 19

2. Cellular Differentiation:

Well	Moderately	Poor

3. Nuclear Atypia:

Nuclear Appearance		0	I	II	III
Aniso Nucleosis					X
Hyperchromatism					X
Nucleolar Prominent					X
Multinucleated Giant Cell					X
Mitotic Activity					X
Nuclear Grade					X

Histological Diagnosis:

Diffuse and non-diffuse poorly differentiated

Comments:

Adenocarcinoma, G3

Director, Research Pathology

Date

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file f1c9cb69-4a8e-47ad-bbf5-9c7fbbd71f8b (TCGA-CD-A4MG.E71CA74E-83C3-48E8-818C-9F06E83E0252.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).